Gene-level copy-number profile of tumor specimen CDDP-ACQQ-TTP1-A from CDDP_EAGLE case CDDP-ACQQ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63 years.
Specimen CDDP-ACQQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77e78f27-782e-4742-873c-844d657a9c2d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACQQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,292 have no estimate.
https://portal.gdc.cancer.gov/files/50845c32-090d-40e9-ab51-26f864990cf0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 529; copy number 3: 16,003; copy number 4: 36,531; copy number 5: 3,925; copy number 6: 773; copy number 7: 484; copy number 8: 62; copy number 9: 9; copy number 10: 3; copy number 17: 8; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,373,659, 8 genes, copy number 17: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr5:10,337,277–10,343,131, 2 genes, copy number 9: Y_RNA, AC012640.5.
- chr7:5,526,409–5,563,902, 3 genes, copy number 10 (within-gene range 4–10): ACTB, AC006483.2, AC006483.1.
- chr7:102,433,106–102,517,777, 7 genes, copy number 9 (within-gene range 6–9): ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B.
- chr22:21,396,273–21,396,590, 1 gene, copy number 27: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
